Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8328, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8328-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Patient with renal mass.

Specimens Submitted:

- 1: SP: Lt. kidney [REDACTED]
- 2: SP: Para-aortic lymph node [REDACTED]
- 3: SP: Hilar lymph node [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, LEFT; EXCISION:
- RENAL CELL CARCINOMA, CHROMOPHOBE TYPE. THE TUMOR GREATEST DIAMETER IS 13.5 CM. THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FIBROSIS AND FOCAL CHRONIC INFLAMMATION. TUMOR EXTENDS INTO THE RENAL SINUS. TUMOR BULGES INTO THE RENAL PELVIS BUT DOES NOT EXTEND INTO IT. THE ADRENAL GLAND IS NOT SUBMITTED. TUMOR SHOWS FOCAL NECROSIS AND HYALINIZATION. VASCULAR INVASION PRESENT WITHIN THE RENAL SINUS.
- 2) LYMPH NODE, PARA-AORTIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 3) LYMPH NODE, HILAR; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

[REDACTED]

[REDACTED]

1) The specimen is received fresh for frozen section and is labeled "Left kidney". It consists of a kidney, with perinephric fat, portion of ureter and hilar vessels. The adrenal gland not present. The overall dimensions of the specimen are 26 x 15 x 8.5 cm. The kidney weighs 1542 grams. The renal capsule strips off easily. The kidney measures 18 x 6.5 x 6.4 cm. Within the parenchyma of the kidney there is a yellow-tan mass measuring 13.5 in greatest dimension. The tumor appears to extend into the perirenal fat. The remainder of the renal parenchyma exhibits no abnormalities. The renal pelvis appears involve by tumor. The renal sinus appears involve by tumor. The renal vein appears uninvolved by tumor. The perirenal fat is unremarkable. The segment of ureter measures 4.2 cm in Length and is unremarkable. Representative sections are submitted.

Summary of sections:

FSC - frozen section control
T-tumor

[page 2 of 2]
TN-tumor and normal
TC-tumor and capsule
NK-normal kidney
RP-renal pelvis
UM-ureteral margin
VM-vascular margin

2) The specimen is received in formalin, labeled "Para-aortic lymph node". It consists of fibrofatty tissue fragments. Entirely submitted.

Summary of Sections:
U - undesignated

3) The specimen is received in formalin, labeled "Hilar lymph node". It consists of a single lymph node embedded in adipose tissue measuring 1 cm in greatest dimension. Entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Lt. kidney

Block	Sect. Site	PCs
1	FSC	1
1	NK	1
2	RP	2
5	T	5
1	TC	1
3	TN	3
1	UM	1
1	VM	1

Part 2: SP: Para-aortic lymph node

Block	Sect. Site	PCs
1	U	1

Part 3: SP: Hilar lymph node

Block	Sect. Site	PCs
1	U	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL CARCINOMA (VER)
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file a9b845cb-a78a-4440-8a31-0a2fe3e31fd8 (TCGA-KL-8328.AED25FD2-56A8-4B87-8351-82EC4A7AC271.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).